Somatic mutation profile of tumor specimen ALCH-B3KB-TTP1-A (aliquot ALCH-B3KB-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3KB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,981 days).
Specimen ALCH-B3KB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7db2e7b8-3730-4fb9-972a-48bfafb8eaed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3KB-NB1-A (Blood Derived Normal), aliquot ALCH-B3KB-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ed387a-f379-4c22-893e-9bce58dbb69c

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Splice Site 2, RNA 2, 3'UTR 2, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by mutect2, varscan2
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 57/235 reads (24%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANKRD17 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.067); catalogued as rs1263743729; called by muse, mutect2
- CACNA1F | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs782237261; called by muse, mutect2
- CSMD1 | c.5888G>A p.R1963H (on ENST00000520002; = p.R1962H on NM_033225.6) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057015722, COSV59325348; called by muse, mutect2
- CWH43 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1263037689; called by muse, mutect2
- EXD2 | c.1456G>A p.G486S (on ENST00000312994 / NM_001193362.1; = p.G361S on NM_018199.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs150337966; called by muse, mutect2, varscan2
- H2BC21 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV58613197; called by muse, mutect2, varscan2
- NLRP1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201736619, COSV99335916; called by muse, mutect2, varscan2
- OR5B12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs139365126; called by muse, mutect2, varscan2
- OSGEP | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1290770454; called by muse, mutect2
- PLS3 | c.876del p.F292Lfs*30 | Frame Shift Del (DEL) | VAF 29/194 reads (15%) | catalogued as COSV99171692; called by mutect2, pindel, varscan2
- STXBP1 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs1381421236, COSV100964606; called by muse, mutect2
- TMEM81 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1453086559; called by muse, mutect2, varscan2
- TPH2 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100421880; called by muse, mutect2, varscan2
- XDH | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65147050, COSV65151254; called by muse, mutect2, varscan2
- ZNFX1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100870700; called by muse, mutect2
- ABHD16B | c.1302del p.R435Afs*? | Frame Shift Del (DEL) | VAF 3/16 reads (19%) | called by pindel, varscan2
- AFF2 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.174); called by muse, mutect2
- ATM | c.1065+2T>C p.X355_splice | Splice Site (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- BCAS2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCDC173 | c.596A>T p.E199V | Missense Mutation (SNP) | VAF 22/391 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- DIP2A | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM126A | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- FBN2 | c.2840G>T p.R947M | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FIGNL2 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- HFM1 | c.2982+1G>T p.X994_splice | Splice Site (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2
- HFM1 | c.2982G>T p.Q994H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HPS3 | c.1334T>G p.I445S | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2
- HTT | c.8557G>A p.A2853T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2
- JCAD | c.3656T>C p.F1219S | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KTN1 | c.3496G>C p.V1166L (on ENST00000395314 / NM_001271014.2; = p.V1137L on NM_004986.4) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LRRC9 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- NEB | c.13823G>T p.G4608V | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NIN | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OLFML2B | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PCDH17 | c.857T>G p.V286G | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2
- PCDHA6 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SH2D3A | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1962G>C p.W654C | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- USP48 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- WDR81 | c.1637A>T p.D546V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMAT1 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- BTAF1 | c.4020T>C p.H1340= | Silent (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- ERBIN | c.3333C>T p.H1111= | Silent (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- GSDMD | c.501G>A p.Q167= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs916361550; called by muse, mutect2, varscan2
- HAPLN3 | c.202C>T p.L68= | Silent (SNP) | VAF 2/30 reads (7%) | called by muse, mutect2
- HSPA13 | c.909A>G p.Q303= | Silent (SNP) | VAF 24/331 reads (7%) | catalogued as rs375337606; called by muse, mutect2
- MINDY4B | c.459G>A p.V153= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- NOS1 | c.2199C>T p.A733= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- RMC1 | c.1683A>C p.A561= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2
- SPP1 | c.429C>T p.T143= (on ENST00000395080 / NM_001040058.2; = p.T129= on NM_000582.2) | Silent (SNP) | VAF 24/330 reads (7%) | catalogued as rs535179470, COSV52952646; called by muse, mutect2
- TBC1D4 | c.3442C>T p.L1148= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- TOPORS | c.384A>G p.V128= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- TPH2 | c.1140C>A p.L380= | Silent (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- TTC28 | c.1701G>A p.L567= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- UBR5 | c.3600C>T p.G1200= | Silent (SNP) | VAF 20/309 reads (6%) | called by muse, mutect2
- DAAM2 | c.*2770C>T | 3'UTR (SNP) | VAF 12/216 reads (6%) | catalogued as rs957515085; called by muse, mutect2
- OR6W1P | n.793C>A | RNA (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- TMEM70 | c.*883T>C | 3'UTR (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2
- ZNF300P1 | n.1392C>A | RNA (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
